Somatic mutation profile of tumor specimen TCGA-FI-A2F9-01A (aliquot TCGA-FI-A2F9-01A-11D-A17D-09) from TCGA case TCGA-FI-A2F9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 79.1 years (28,886 days).
Specimen TCGA-FI-A2F9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a745196-20e2-4b7b-af24-d410ccb585c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FI-A2F9-10B (Blood Derived Normal), aliquot TCGA-FI-A2F9-10B-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfa67efb-ccf8-4985-b8fa-f5b6f0d7106b

The open-access MAF lists 48 somatic variants for this specimen: 40 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 32, Silent 8, Frame Shift Del 4, In Frame Del 2, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SOS1 | c.697A>T p.N233Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen possibly damaging (0.671); catalogued as rs1057519963, COSV67673722; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.618); catalogued as rs962019378, COSV54353807; called by muse, mutect2, varscan2
- ADRA1A | c.1304G>A p.C435Y | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV99369820; called by muse, mutect2, varscan2
- ANKRD50 | c.2914G>A p.V972I | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.251); catalogued as rs746569251, COSV72385790; called by muse, mutect2, varscan2
- APC | c.2222A>G p.N741S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.035); catalogued as rs150209825; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, varscan2
- BMP4 | c.259T>C p.Y87H | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99816716; called by muse, mutect2, varscan2
- DPP3 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.687); catalogued as rs772573325, COSV100855407, COSV64756305; called by muse, mutect2, varscan2
- HS2ST1 | c.1051A>G p.I351V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as COSV100777622; called by muse, mutect2, varscan2
- ITPR3 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs773223069, COSV65415388; called by muse, mutect2, varscan2
- KHNYN | c.1036C>G p.R346G | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99249321; called by muse, mutect2, varscan2
- LRRC8A | c.1542C>G p.S514R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV99396205; called by muse, mutect2, varscan2
- MON2 | c.3103G>T p.D1035Y | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99741431; called by muse, mutect2, varscan2
- MPDZ | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.116); catalogued as rs767694605, COSV100056085; called by muse, mutect2, varscan2
- ODAM | c.146C>A p.P49Q | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV101258017; called by muse, mutect2
- PEF1 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs765386131, COSV101035765; called by muse, mutect2, varscan2
- PGAM1 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV100602389; called by muse, mutect2, varscan2
- PIK3CA | c.2174A>G p.D725G | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV55889334; called by muse, mutect2, varscan2
- PNLIPRP3 | c.71G>A p.R24K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV100982308, COSV65049479; called by muse, mutect2, varscan2
- RBFOX1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs755458164, COSV60948155; called by muse, mutect2, varscan2
- RNF7 | c.119T>C p.M40T | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs1403797604, COSV99857873; called by muse, mutect2, varscan2
- SKIL | c.1900G>A p.A634T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99377997; called by mutect2, varscan2
- SLC22A9 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs756160377, COSV54166826; called by muse, mutect2, varscan2
- SLC44A5 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1448880992, COSV100900951; called by muse, mutect2, varscan2
- SNAPC4 | c.2712G>C p.E904D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1246337535, COSV100046739; called by muse, mutect2
- SRGAP1 | c.2433C>A p.S811R | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100754200; called by muse, mutect2, varscan2
- STAP1 | c.256A>T p.N86Y | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV99609106; called by muse, mutect2, varscan2
- STK39 | c.943del p.S315Hfs*18 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as COSV63600120; called by mutect2, pindel, varscan2
- TFAP4 | c.419C>G p.P140R | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV99200022, COSV99200041; called by muse, mutect2, varscan2
- TMC3 | c.639C>A p.Y213* | Nonsense Mutation (SNP) | VAF 23/30 reads (77%) | catalogued as COSV100845830; called by muse, mutect2, varscan2
- TRIML2 | c.847A>C p.N283H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100455839; called by muse, mutect2, varscan2
- USP31 | c.3742G>T p.A1248S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV104376259, COSV99564539; called by muse, mutect2, varscan2
- YAE1 | c.524A>G p.H175R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs767147083, COSV56233473; called by muse, mutect2, varscan2
- ZBTB25 | c.1083G>T p.K361N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV101170699; called by muse, mutect2, varscan2
- ZNF337 | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1569005228, COSV99429971; called by muse, mutect2, varscan2
- AASDH | c.740_742del p.V247del | In Frame Del (DEL) | VAF 7/18 reads (39%) | called by mutect2, varscan2
- ETV4 | c.438del p.G147Dfs*17 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- JUP | c.1559_1561del p.E520del | In Frame Del (DEL) | VAF 14/43 reads (33%) | called by pindel, varscan2
- P4HA3 | c.430del p.Q144Rfs*8 | Frame Shift Del (DEL) | VAF 15/33 reads (45%) | called by mutect2, pindel, varscan2
- TAF1 | c.2014_2016dup p.M672dup (on ENST00000373790 / NM_138923.4; = p.M693dup on NM_004606.5 and 1 other RefSeq transcript) | In Frame Ins (INS) | VAF 35/51 reads (69%) | called by mutect2, pindel, varscan2
- ZNF385D | c.77del p.P26Lfs*38 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | called by mutect2, pindel, varscan2
- ANK3 | c.5982G>A p.S1994= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as rs148277967; called by muse, mutect2, varscan2
- MALT1 | c.1200C>T p.L400= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV61933973; called by muse, mutect2, varscan2
- PCDHGA8 | c.1950C>A p.G650= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as COSV99529461; called by muse, mutect2, varscan2
- POLR1A | c.3474A>C p.S1158= | Silent (SNP) | VAF 51/59 reads (86%) | catalogued as rs1342916635, COSV99807044; called by muse, mutect2, varscan2
- POU1F1 | c.751C>T p.L251= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV99773191; called by muse, mutect2, varscan2
- PYGL | c.1722C>T p.Y574= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99368185; called by muse, mutect2, varscan2
- TNXB | c.8019G>A p.S2673= (on ENST00000647633; = p.S2426= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs370586724; called by muse, mutect2, varscan2
- TSR1 | c.81A>G p.A27= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV99279673; called by muse, mutect2, varscan2
